Somatic mutation profile of tumor specimen ER-AD8S-TTP1-A (aliquot ER-AD8S-TTP1-A-1-0-D-A75J-34) from EXCEPTIONAL_RESPONDERS case ER-AD8S, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 76.6 years (27,991 days).
Specimen ER-AD8S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1168e9c-d2f0-4dd6-ba7c-923a089dceb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-AD8S-NB1-A (Blood Derived Normal), aliquot ER-AD8S-NB1-A-1-0-D-A75J-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd90d430-462c-4930-b1c6-7cfc4a30a7ab

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Nonsense Mutation 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD11 | c.3008A>C p.K1003T (on ENST00000280758 / NM_001018072.2; = p.K540T on NM_001017523.2) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen probably damaging (0.946); catalogued as COSV55025836, COSV55028973, COSV55038748; called by muse, mutect2
- COL4A1 | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1461754052; ClinVar: likely pathogenic; called by muse, mutect2
- CRB1 | c.1888T>G p.F630V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100957836, COSV100958101, COSV66328724; called by muse, mutect2
- MTO1 | c.1307C>T p.T436I (on ENST00000370300 / NM_133645.3; = p.T411I on NM_012123.4) | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398122419, CM1310694; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 12/121 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs1057520008, CD100447, COSV52760580, COSV52806341, COSV52877975, COSV52979708; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2
- ALLC | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs540254607; called by muse, mutect2, varscan2
- BRCA2 | c.6058G>A p.E2020K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs80358842, CM101422, COSV66450746; ClinVar: uncertain significance; called by mutect2, varscan2
- ACER1 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- ADGRD1 | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATR | c.6319G>A p.A2107T | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2
- CDK9 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); called by muse, mutect2
- ELAPOR2 | c.1912C>T p.P638S (on ENST00000450689 / NM_001142749.3; = p.P471S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2
- FSIP2 | c.16780G>T p.E5594* | Nonsense Mutation (SNP) | VAF 11/132 reads (8%) | called by muse, mutect2
- GRIA3 | c.2529G>T p.L843F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.249); called by mutect2, varscan2
- LAMA1 | c.7432A>T p.R2478* | Nonsense Mutation (SNP) | VAF 20/246 reads (8%) | called by muse, mutect2
- MLF1 | c.94A>C p.S32R | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- MYH10 | c.2268G>C p.L756F | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NOS3 | c.1659G>A p.M553I | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SMG1 | c.8197G>A p.V2733I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SPART | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STIM2 | c.1143A>C p.K381N | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF257 | c.1141T>C p.F381L | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2
- RET | c.6G>A p.A2= | Silent (SNP) | VAF 18/504 reads (4%) | catalogued as rs1243883489; ClinVar: likely benign; called by muse, mutect2
- SOX18 | c.564C>G p.P188= | Silent (SNP) | VAF 26/302 reads (9%) | catalogued as COSV100450573; called by muse, mutect2
- STX11 | c.729C>T p.N243= | Silent (SNP) | VAF 15/165 reads (9%) | catalogued as rs534184432; called by muse, mutect2
- TDRD15 | c.808T>C p.L270= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- WNT6 | c.732C>T p.R244= | Silent (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 4/34 reads (12%) | catalogued as rs201441562; called by pindel, varscan2
- OR2L2 | c.*65A>G | 3'UTR (SNP) | VAF 9/121 reads (7%) | catalogued as COSV100823813, COSV63549463, COSV63558660; called by muse, mutect2
